Surgical pathology report (de-identified scan), TCGA case TCGA-AP-A0LG, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site MSKCC, specimen TCGA-AP-A0LG-01A (Primary Tumor).

[page 1 of 2]
1CD-0-3

Specimens Submitted:

- 1: SP: Uterus, cervix, rt. fallopian tube & ovary
- 2: SP: Rt. para-aortic lymph nodes
- 3: SP: Lt. para-aortic lymph nodes
- 4: SP: Lt. external iliac lymph nodes
- 5: SP: Lt. obturator lymph nodes
- 6: SP: Rt. external iliac lymph nodes
- 7: SP: Rt. obturator lymph nodes

adenocarcinoma, endometrioid, NOS
8380/3
Site: Endometrium CS4.1
hw
5/1/11

DIAGNOSIS:

- 1) UTERUS, CERVIX, RIGHT ADNEXA; HYSTERECTOMY WITH RIGHT SALPINGO-OOPHORECTOMY:
- ADENOCARCINOMA OF ENDOMETRIUM, ENDOMETRIOID TYPE, NOS, FIGO GRADE II (6-50% SOLID GROWTH), NUCLEAR GRADE 2 WITH FOCAL NUCLEAR GRADE 3.
- THE TUMOR INVADERS TO <= HALF OF MYOMETRIUM.
- THE MAXIMAL THICKNESS OF MYOMETRIAL INVASION IS 4 MM. THE THICKNESS OF THE MYOMETRIUM IN THE AREA OF MAXIMAL TUMOR INVASION IS 22 MM.
- NO ENDOCERVICAL INVASION IS IDENTIFIED.
- NO VASCULAR INVASION IS IDENTIFIED.
- THE ENDOMETRIUM SHOWS THE FOLLOWING ABNORMALITY: COMPLEX HYPERPLASIA WITH ATYPIA.
- THE MYOMETRIUM SHOWS THE FOLLOWING ABNORMALITY: ADENOMYOSIS.
- ALL ADNEXAE ARE UNREMARKABLE.
- 2) LYMPH NODES, RIGHT PARA-AORTIC; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).
- 3) LYMPH NODES, LEFT PARA-AORTIC; EXCISION:
- ONE BENIGN LYMPH NODE, FIBROVASCULAR AND NERVE TISSUE (0/1).
- 4) LYMPH NODES, LEFT EXTERNAL ILIAC; EXCISION:
- BENIGN FIBROADIPOSE TISSUE, NO LYMPH NODE PRESENT.
- 5) LYMPH NODES, LEFT OBTURATOR; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).

** Continued on next page **

Histology Discrepancy		☒

[page 2 of 2]
- 6) LYMPH NODES, RIGHT EXTERNAL ILIAC; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).
- 7) LYMPH NODES, RIGHT OBTURATOR; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[REDACTED]

Source: NCI Genomic Data Commons file c3d2bc2f-d82e-43b7-8624-53d836630e44 (TCGA-AP-A0LG.7343A9B5-276E-4EE1-AC06-27835D63B0E2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).